Surgical pathology report (de-identified scan), TCGA case TCGA-J4-8200, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-8200-01A (Primary Tumor).

[page 1 of 4]
MRN

Name

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. RIGHT PELVIC LYMPH NODES-
- B. LEFT PELVIC LYMPH NODES-
- C. TISSUE OVER PROSTATE-
- D. PROSTATE, SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODES-
TWO LYMPH NODES, NEGATIVE FOR TUMOR.
- B. LEFT PELVIC LYMPH NODES-
TWO LYMPH NODES, NEGATIVE FOR TUMOR.
- C. TISSUE OVER PROSTATE-
FATTY TISSUE, NO TUMOR SEEN.
- D. PROSTATE, SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: RIGHT AND LEFT PROSTATE, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 29 GRAMS. SIZE: 4 x 3.5 x 3 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: NOT SEEN.

SEVERITY IN EXTENT OF TUMOR: 3/5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

[page 2 of 4]
DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT SEEN.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT2c, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: FOCALLY PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

Case Clinical Information
PROSTATE CANCER

Gross Description

A. Received in formalin labeled "right pelvic lymph nodes" are two nodules of tan fatty tissue consistent with lymphoid tissue from 2.5 cm. down to 1 cm. The excess fat is trimmed. Both nodes are submitted in A1.

B. Received in formalin labeled "left pelvic nodes" are two nodules of fatty tissue, each measuring 1 cm. The excess fat is trimmed. Both nodes are submitted in B1.

C. Received in formalin labeled "tissue over prostate" is a 2.5 cm. aggregate of tan fatty tissue. No palpable masses are identified. The entire specimen is submitted in C1.

D. Received in formalin labeled "prostate, seminal vesicle and vas deferens" is a radical prostatectomy specimen which includes a 29 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 4 x 3.5 x 3 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 3 x 1 x 1 cm. The right vas measures 4.5 cm. The left seminal vesicle measures 3 x 1 x 1 cm. The left vas measures 3.5 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities.

[page 3 of 4]
Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in D1-D6 ; bladder resection margin D7,8; complete section of mid gland anterior D9,10; posterior D11,12; complete section of upper third of gland, anterior D13,14; posterior D15,16; remainder of the posterior gland entirely submitted in D17-20; D21- right seminal vesicle and vas deferens; D22 left seminal vesicle and vas deferens; D23- tumor taken for research; D24; non-tumor taken for research.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.7
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.8
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.9
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.10
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.11
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.12
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.13
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.14

[page 4 of 4]
H&E X1
D. AA ROUTINE H&E X1 BLOCK.15
H&E X1
D. AA ROUTINE H&E X1 BLOCK.16
H&E X1
D. AA ROUTINE H&E X1 BLOCK.17
H&E X1
D. AA ROUTINE H&E X1 BLOCK.18
H&E X1
D. AA ROUTINE H&E X1 BLOCK.19
H&E X1
D. AA ROUTINE H&E X1 BLOCK.20
H&E X1
D. AA ROUTINE H&E X1 BLOCK.21
H&E X1
D. AA ROUTINE H&E X1 BLOCK.22
H&E X1
D. AA ROUTINE H&E X1 BLOCK.23
H&E X1
D. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Source: NCI Genomic Data Commons file eacdbfb2-e342-4aed-8e30-932923de6dc9 (TCGA-J4-8200.5E18C318-D20B-4837-850D-34FD96C87EEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).